Somatic mutation profile of tumor specimen TARGET-10-PANVUD-09A (aliquot TARGET-10-PANVUD-09A-01D) from TARGET case TARGET-10-PANVUD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.6 years (3,503 days).
Specimen TARGET-10-PANVUD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e88ea77f-c6f2-4c39-a158-6f361dcb59b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVUD-14A (Bone Marrow Normal), aliquot TARGET-10-PANVUD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15e5e195-0cf3-4d1b-90db-11812e194420

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Nonsense Mutation 3, RNA 2, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC141 | c.725G>A p.W242* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as rs530766141; called by muse, mutect2
- MBD3L1 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1248026467; called by muse, mutect2, varscan2
- BCAR3 | c.1199G>T p.C400F | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.063); called by muse, mutect2
- BCL9 | c.3242G>C p.G1081A | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DDX10 | c.1227C>A p.Y409* | Nonsense Mutation (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- DDX60L | c.1528G>T p.D510Y | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- DNAH12 | c.8489G>T p.S2830I (on ENST00000351747; = p.S3698I on NM_001366028.2) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.438); called by muse, mutect2
- FEM1A | c.570C>A p.C190* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | called by muse, varscan2
- HEPH | c.1711C>A p.Q571K (on ENST00000343002; = p.Q304K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MCM7 | c.857G>T p.R286L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2
- MED13 | c.1024G>T p.V342F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- OR56B1 | c.612C>A p.N204K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); called by mutect2, varscan2
- OTUD7A | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- PCDHGC4 | c.46_49del p.T16Ffs*29 | Frame Shift Del (DEL) | VAF 18/41 reads (44%) | called by mutect2, varscan2*
- PKMYT1 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.026); called by muse, mutect2
- TCTN3 | c.844G>T p.V282F | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, varscan2
- UROS | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AKAP5 | c.1041C>A p.I347= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- MYH4 | c.810G>T p.L270= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- MIR655 | n.91C>A | RNA (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- NBPF22P | n.336C>T | RNA (SNP) | VAF 39/116 reads (34%) | catalogued as rs752349201; called by muse, mutect2, varscan2
